Somatic mutation profile of tumor specimen TCGA-G3-A7M8-01A (aliquot TCGA-G3-A7M8-01A-11D-A33Q-10) from TCGA case TCGA-G3-A7M8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 31.6 years (11,527 days).
Specimen TCGA-G3-A7M8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c30e200-4bd6-4dfd-a3f8-43828068051c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A7M8-10A (Blood Derived Normal), aliquot TCGA-G3-A7M8-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7268bab-c5dc-465b-aaa2-6eb0ec669dc8

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV70042645; called by mutect2, varscan2
- AHNAK | c.15116A>T p.K5039I | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV57228739; called by muse, mutect2, varscan2
- ASPM | c.6466G>C p.G2156R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as COSV54137793; called by muse, mutect2, varscan2
- BCL11A | c.2090G>A p.G697D (on ENST00000335712 / NM_001365609.1; = p.G731D on NM_018014.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59636384; called by muse, mutect2
- CLVS2 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.093); catalogued as COSV51565189; called by muse, mutect2
- CTC1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV59855293; called by muse, mutect2, varscan2
- FZR1 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV58053547; called by muse, mutect2, varscan2
- GRIA2 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.289); catalogued as rs147349807; called by muse, mutect2, varscan2
- IL1F10 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV100520210; called by muse, varscan2
- INSR | c.3631G>A p.G1211R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57172469; called by muse, mutect2, varscan2
- KIAA1210 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs781323631, COSV68179878; called by muse, mutect2, varscan2
- PGBD4 | c.203A>C p.D68A | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.007); catalogued as COSV56629020; called by muse, mutect2, varscan2
- PIWIL4 | c.2242C>A p.Q748K | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV54412224; called by muse, mutect2, varscan2
- PLEKHA6 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV55339711; called by muse, mutect2, varscan2
- SNX2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV101075781; called by muse, mutect2
- TNKS | c.1876A>G p.T626A | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV60065825; called by muse, mutect2, varscan2
- ZNF91 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV56088043, COSV56091010; called by muse, varscan2
- HOXB7 | c.246G>T p.P82= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV53311469; called by muse, mutect2, varscan2
- LRPPRC | c.204T>C p.I68= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as COSV53242861; called by muse, mutect2
- LRRC49 | c.1734C>T p.S578= | Silent (SNP) | VAF 31/347 reads (9%) | catalogued as rs1186776268, COSV53014983; called by muse, mutect2
- NSUN2 | c.1992T>C p.D664= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs1038468036, COSV52956918; called by muse, mutect2, varscan2
- PTGDR | c.708G>A p.P236= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1172867034, COSV60094994; called by muse, mutect2, varscan2
- SNED1 | c.1125C>T p.C375= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs1173949099, COSV60023639; called by muse, mutect2, varscan2
- UTP20 | c.237T>C p.N79= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV55384675; called by muse, mutect2, varscan2
